Somatic mutation profile of tumor specimen TARGET-10-PARMKK-09A (aliquot TARGET-10-PARMKK-09A-01D) from TARGET case TARGET-10-PARMKK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,222 days).
Specimen TARGET-10-PARMKK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b3695a0-57af-4185-af22-f5d88d6f82ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARMKK-14A (Bone Marrow Normal), aliquot TARGET-10-PARMKK-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c65e939-5709-4573-a84e-fc1a824b5c3d

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, 3'UTR 2, Nonsense Mutation 2, Frame Shift Del 1, 5'UTR 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CD | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 60/119 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs397518423, CM067447, COSV63126880; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.214); catalogued as rs530202564, COSV60912732; called by muse, mutect2, varscan2
- AK6 | c.340A>G p.K114E | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV66458616; called by muse, mutect2, varscan2
- BLOC1S4 | c.417G>T p.E139D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.274); catalogued as COSV57900982; called by muse, mutect2, varscan2
- DOCK1 | c.5422G>A p.V1808M | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs779069875, COSV54736133; called by muse, mutect2, varscan2
- FBH1 | c.2893G>A p.V965M (on ENST00000362091 / NM_178150.3; = p.V1016M on NM_032807.4) | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as rs371208439; called by muse, mutect2, varscan2
- KMT2D | c.9166G>T p.E3056* | Nonsense Mutation (SNP) | VAF 19/124 reads (15%) | catalogued as COSV56428455; called by muse, mutect2, varscan2
- LGR6 | c.1927C>T p.R643W (on ENST00000367278 / NM_001017403.1; = p.R591W on NM_021636.3) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs141415011; called by muse, mutect2, varscan2
- NAT10 | c.2173C>T p.R725* | Nonsense Mutation (SNP) | VAF 46/109 reads (42%) | catalogued as rs772895064, COSV57663152; called by muse, mutect2, varscan2
- NOTCH1 | c.5039T>A p.I1680N | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53025693, COSV53032125, COSV53096766; called by muse, mutect2, varscan2
- RYR3 | c.3215G>A p.R1072Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373473539, COSV66784510; called by muse, mutect2, varscan2
- SLC25A16 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.227); catalogued as rs760386255, COSV56264741; called by muse, mutect2, varscan2
- PRDM2 | c.3087del p.S1030Lfs*11 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | called by mutect2, pindel, varscan2
- ITGA3 | c.636C>T p.F212= | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as rs545806805, COSV50305975; called by muse, mutect2, varscan2
- ZBTB20 | c.1551G>A p.A517= (on ENST00000474710 / NM_001164342.2; = p.A444= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as rs747213174, COSV61846085; called by muse, mutect2, varscan2
- DRC7 | c.1975-64C>T | Intron (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2, varscan2
- MRM2 | c.*60T>C | 3'UTR (SNP) | VAF 13/23 reads (57%) | called by muse, mutect2, varscan2
- PRRT1B | c.*43G>A | 3'UTR (SNP) | VAF 7/48 reads (15%) | catalogued as rs947674308; called by muse, mutect2, varscan2
- SCAMP2 | c.-72C>G | 5'UTR (SNP) | VAF 14/28 reads (50%) | catalogued as rs532440677; called by muse, varscan2
- ZNF578 | chr19:52451350 C>T | 5'Flank (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
